Somatic mutation profile of tumor specimen 0DMN22 from CCDI case PBCAKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,867 days).
Specimen 0DMN22: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f20cfc62-5623-4ed7-b21c-4c567341b482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN15 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27de0356-9f0d-4f21-9eaf-8bd313757060

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, In Frame Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 360/632 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469669, COSV61329437, COSV61329567, COSV61330093; ClinVar: not provided / other; called by muse, varscan2
- ANKFN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 322/1130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1287743848, COSV59446410; called by muse, varscan2
- ANO1 | c.1580T>C p.I527T | Missense Mutation (SNP) | VAF 216/430 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs745855980; called by muse, varscan2
- CCDC168 | c.6236C>A p.S2079* | Nonsense Mutation (SNP) | VAF 612/1335 reads (46%) | catalogued as rs1215122703, COSV70555100; called by muse, varscan2
- GAS7 | c.755C>T p.A252V (on ENST00000432992 / NM_201433.2; = p.A112V on NM_003644.3) | Missense Mutation (SNP) | VAF 358/1368 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765522796, COSV60445575; called by muse, varscan2
- GPR101 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 436/468 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as COSV99981200; called by muse, varscan2
- KBTBD4 | c.888_889insGGG p.R296_R297insG | In Frame Ins (INS) | VAF 242/687 reads (35%) | catalogued as COSV58597484; called by pindel, varscan2
- KRT8 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 333/821 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs571462252, CM1210284, COSV53177535; called by muse, varscan2
- MAP1A | c.7415G>A p.R2472Q | Missense Mutation (SNP) | VAF 304/1112 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs148897210, COSV55812231; called by muse, varscan2
- SLC25A31 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 434/916 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1480124960; called by muse, varscan2
- GTF3A | c.531C>G p.S177R | Missense Mutation (SNP) | VAF 284/678 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, varscan2
- MROH5 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 147/569 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR10H5 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 536/1052 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, varscan2
- OR8G5 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 247/886 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, varscan2
- ANKRD30A | c.402C>T p.L134= (on ENST00000611781; = p.L78= on NM_052997.2) | Silent (SNP) | VAF 908/1882 reads (48%) | catalogued as rs914914903, COSV64609437, COSV64614180; called by muse, varscan2
- DUSP9 | c.507C>T p.S169= | Silent (SNP) | VAF 274/511 reads (54%) | catalogued as rs143362612, COSV100720176; called by muse, varscan2
- RFX1 | c.2139C>T p.N713= | Silent (SNP) | VAF 350/796 reads (44%) | called by muse, varscan2
- SELP | c.489C>T p.C163= | Silent (SNP) | VAF 214/602 reads (36%) | called by muse, varscan2
- TNFSF13 | c.612G>T p.P204= | Silent (SNP) | VAF 560/1246 reads (45%) | called by muse, varscan2
- CDH8 | c.1536+45C>T | Intron (SNP) | VAF 287/600 reads (48%) | called by muse, varscan2
